Somatic mutation profile of tumor specimen HCM-BROD-0724-C43-06A (aliquot HCM-BROD-0724-C43-06A-01D-A85C-36) from HCMI case HCM-BROD-0724-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.4 years (27,189 days).
Specimen HCM-BROD-0724-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb96073a-edee-49a4-99f2-2dbbced44712.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0724-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0724-C43-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c1a0c4e-c097-485b-97d8-4d15d7a014f2

The open-access MAF lists 2,514 somatic variants for this specimen: 1,607 protein-altering or splice-affecting, 809 silent, 98 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,453, Silent 809, Nonsense Mutation 95, Intron 54, Splice Region 24, Splice Site 18, 3'UTR 12, 5'Flank 12, Frame Shift Del 9, 5'UTR 8, RNA 7, Translation Start Site 5.

Variants (750 of 2,514; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.4375C>T p.R1459C | Missense Mutation (SNP) | VAF 118/694 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72547524, CM030403; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 861/928 reads (93%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, varscan2
- CLDN16 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 381/571 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs104893728, CM076116, CM993501; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MED23 | c.3982C>T p.R1328C | Missense Mutation (SNP) | VAF 288/301 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766478634, COSV51580995; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYBPC1 | c.877C>T p.R293* (on ENST00000550270 / NM_206820.2; = p.R318* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 43/207 reads (21%) | catalogued as rs397515422, CM129132, COSV62250776; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6705-1G>A p.X2235_splice (on ENST00000358273 / NM_001042492.3; = p.X2214_splice on NM_000267.3) | Splice Site (SNP) | VAF 189/196 reads (96%) | catalogued as rs1060500356, CS000886, COSV62198415; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 630/658 reads (96%) | catalogued as rs1567555994, CM156961, COSV52702138, COSV53867973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 102/471 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as COSV51008208; called by muse, varscan2
- ABCA12 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 120/235 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV99790847; called by muse, mutect2, varscan2
- ABCA9 | c.4390C>T p.R1464W | Missense Mutation (SNP) | VAF 225/518 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374873743; called by muse, varscan2
- ABCB7 | c.198G>A p.W66* (on ENST00000373394 / NM_001271696.3; = p.W67* on NM_004299.6) | Nonsense Mutation (SNP) | VAF 63/186 reads (34%) | catalogued as COSV53723309; called by muse, mutect2, varscan2
- ACAD10 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 151/542 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1279452264; called by muse, varscan2
- ACAP3 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 208/1350 reads (15%) | catalogued as COSV100686591; called by muse, varscan2
- ACE2 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 213/447 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs961360700; called by muse, mutect2, varscan2
- ACSL4 | c.298G>A p.E100K (on ENST00000340800 / NM_022977.2; = p.E59K on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/478 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV61615832, COSV61615891; called by muse, mutect2, varscan2
- ACSM1 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 96/338 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs201624784; called by muse, mutect2, varscan2
- ACSS3 | c.1531G>A p.G511R | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99699369; called by muse, mutect2, varscan2
- ADAMTS20 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 158/269 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs746899207, COSV67125941; called by muse, mutect2, varscan2
- ADAMTS9 | c.5231G>A p.R1744K | Missense Mutation (SNP) | VAF 226/320 reads (71%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV55788685; called by muse, varscan2
- ADCY8 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as rs866330045, COSV53912362; called by muse, varscan2
- ADCY8 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53895961, COSV99654440; called by muse, mutect2, varscan2
- ADGRF4 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 69/455 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV51950717; called by muse, varscan2
- ADGRG4 | c.3524C>T p.S1175F | Missense Mutation (SNP) | VAF 286/649 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV104381527; called by muse, mutect2, varscan2
- ADGRV1 | c.7644G>A p.M2548I | Missense Mutation (SNP) | VAF 228/370 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV67988752; called by muse, mutect2, varscan2
- ADH1A | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 129/496 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52925787; called by muse, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 357/398 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2, varscan2
- ADH1C | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 292/306 reads (95%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs759025388, COSV72463545; called by muse, varscan2
- ADHFE1 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 115/809 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs776500463, COSV52556912; called by muse, mutect2, varscan2
- ADRB2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 214/348 reads (61%) | SIFT tolerated (0.58); PolyPhen benign (0.038); catalogued as rs777431854; called by muse, varscan2
- AFF3 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 66/260 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV100419826; called by muse, varscan2
- AFM | c.1056G>A p.A352= | Splice Region (SNP) | VAF 44/151 reads (29%) | catalogued as rs141061547; called by muse, varscan2
- AGAP2 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 525/838 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); catalogued as rs1253577497; called by muse, varscan2
- AGBL3 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 149/608 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV51951384; called by muse, mutect2, varscan2
- AGK | c.516C>T p.V172= | Splice Region (SNP) | VAF 324/640 reads (51%) | catalogued as COSV100814740; called by muse, varscan2
- AGO2 | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 163/876 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760721583; called by muse, mutect2, varscan2
- AGTR1 | c.920A>T p.K307I | Missense Mutation (SNP) | VAF 82/462 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV62558064; called by muse, varscan2
- AGTR2 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 315/686 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs868921732, COSV64156893; called by muse, mutect2, varscan2
- AHNAK2 | c.5201G>A p.G1734E | Missense Mutation (SNP) | VAF 138/831 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204288052; called by muse, varscan2
- AK7 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 213/700 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs114393353, COSV50870705, COSV50881490; called by muse, varscan2
- AKAP10 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 368/804 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1465814541; called by muse, varscan2
- AKAP6 | c.5093C>T p.S1698F | Missense Mutation (SNP) | VAF 294/553 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55229491, COSV99802282; called by muse, mutect2, varscan2
- AKR1C4 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54122293, COSV54122714; called by muse, mutect2, varscan2
- AKR1D1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 285/548 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV54336211; called by muse, varscan2
- AKR1D1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 227/487 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV54337027; called by muse, varscan2
- AL645922.1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 168/1087 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs145799939; called by muse, varscan2
- ALMS1 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 277/491 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV52513880; called by muse, mutect2, varscan2
- AMY2A | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 228/1374 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs768370675; called by muse, varscan2
- ANKRD2 | c.429C>T p.I143= | Splice Region (SNP) | VAF 125/506 reads (25%) | catalogued as COSV53967782; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 141/624 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs751997383; called by muse, varscan2
- ANKRD30A | c.802C>T p.H268Y (on ENST00000611781; = p.H212Y on NM_052997.2) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1167241084, COSV64610990; called by muse, varscan2
- ANKRD33 | c.71A>G p.N24S (on ENST00000340970 / NM_001304459.2; = p.N159S on NM_182608.4) | Missense Mutation (SNP) | VAF 150/490 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778365098; called by muse, mutect2
- ANO1 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 216/229 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100796915; called by muse, mutect2, varscan2
- ANO2 | c.2278C>T p.P760S (on ENST00000356134 / NM_001278597.3; = p.P764S on NM_001278596.3) | Missense Mutation (SNP) | VAF 132/492 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59037720; called by muse, varscan2
- ANO3 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV99882809; called by muse, mutect2, varscan2
- ANO4 | c.2524G>A p.E842K (on ENST00000392977 / NM_001286615.2; = p.E807K on NM_178826.4) | Missense Mutation (SNP) | VAF 143/527 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV54598610; called by muse, varscan2
- ANPEP | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 282/476 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372186369; called by muse, varscan2
- AP2A1 | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 464/647 reads (72%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.981); catalogued as rs371119628; called by muse, varscan2
- APC | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 99/352 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV57322083, COSV57329454; called by muse, mutect2, varscan2
- APOB | c.12175G>A p.E4059K | Missense Mutation (SNP) | VAF 222/630 reads (35%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.886); catalogued as rs756040945, COSV51956358; called by muse, mutect2, varscan2
- ARAF | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 372/837 reads (44%) | catalogued as rs1452639448, COSV99283501; called by muse, mutect2, varscan2
- ARFGEF3 | c.3229C>T p.P1077S | Missense Mutation (SNP) | VAF 816/875 reads (93%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1293796751; called by muse, varscan2
- ARHGEF5 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 129/1223 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1412421161; called by muse, mutect2, varscan2
- ARMC4 | c.3089A>T p.N1030I | Missense Mutation (SNP) | VAF 144/446 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59474314; called by muse, varscan2
- ARMC5 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 616/841 reads (73%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as rs1473312567; called by muse, mutect2, varscan2
- ARMCX2 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 297/654 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV57530721; called by muse, mutect2, varscan2
- ARSF | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 124/609 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390921374; called by muse, varscan2
- ARSF | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 148/338 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV63840443; called by muse, varscan2
- ASNSD1 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 109/181 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53623847; called by muse, mutect2, varscan2
- ASTN1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 587/626 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs145957941, COSV56082361; called by muse, mutect2, varscan2
- ATG4C | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 73/410 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146646910; called by muse, mutect2, varscan2
- ATP11C | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as COSV59560413, COSV59564678; called by muse, varscan2
- ATP13A5 | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 86/452 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as rs1390039197; called by muse, varscan2
- ATP13A5 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 65/296 reads (22%) | catalogued as COSV60875657; called by muse, mutect2, varscan2
- ATP2B2 | c.2053G>A p.E685K (on ENST00000352432; = p.E651K on NM_001683.5) | Missense Mutation (SNP) | VAF 154/696 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs752661102, COSV59493351; called by muse, varscan2
- ATP6AP2 | c.1040G>A p.R347Q (on ENST00000378438; = p.R348Q on NM_005765.3) | Missense Mutation (SNP) | VAF 107/289 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as COSV65797616; called by muse, mutect2, varscan2
- ATP6V0D2 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); catalogued as COSV53412881; called by muse, mutect2
- ATRNL1 | c.3962C>T p.T1321I | Missense Mutation (SNP) | VAF 233/508 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV58089797; called by muse, mutect2, varscan2
- AXIN2 | c.319A>C p.T107P | Missense Mutation (SNP) | VAF 158/1081 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV61057069; called by muse, varscan2
- AXL | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 413/934 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs201003955, COSV56565179; called by muse, varscan2
- BFAR | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 229/632 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs752398303, COSV55492550; called by muse, mutect2, varscan2
- BHMT2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs746838767; called by muse, mutect2, varscan2
- BMP6 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 340/1044 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs200811682; called by muse, varscan2
- BRAF | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 80/1090 reads (7%) | catalogued as rs770494089, COSV56105105, COSV56366111; called by muse, mutect2
- BRINP2 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 379/407 reads (93%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV64177234; called by muse, mutect2, varscan2
- BTBD16 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV53262020; called by muse, varscan2
- BTBD8 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61544949; called by muse, mutect2, varscan2
- BTBD8 | c.1163G>A p.R388K | Missense Mutation (SNP) | VAF 340/465 reads (73%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.955); catalogued as rs1273079375; called by muse, mutect2, varscan2
- BTBD8 | c.5137G>A p.D1713N (on ENST00000636805 / NM_001376131.1; = p.D1200N on NM_015237.4) | Missense Mutation (SNP) | VAF 77/435 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64885867; called by muse, mutect2, varscan2
- BTC | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 178/284 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as rs782142077; called by muse, mutect2, varscan2
- BTNL3 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 120/424 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1468570079, COSV61564583; called by muse, mutect2, varscan2
- C12orf40 | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 227/395 reads (57%) | SIFT tolerated (0.56); PolyPhen benign (0.234); catalogued as COSV61130335, COSV61130894; called by muse, varscan2
- C12orf42 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 99/388 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV59379932; called by muse, mutect2, varscan2
- C16orf74 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 93/365 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.776); catalogued as rs777069044; called by muse, mutect2, varscan2
- C1QTNF9 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 106/683 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs779386798, COSV59656776; called by muse, varscan2
- C1QTNF9B | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1463638854, COSV65943913; called by muse, varscan2
- C2orf78 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 171/499 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as rs780803582, COSV68518201; called by muse, mutect2, varscan2
- CA10 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 324/750 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs767808441, COSV53350762; called by muse, varscan2
- CABS1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 200/215 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV99909105; called by muse, mutect2, varscan2
- CACNA1B | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 405/430 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1051482739; called by muse, varscan2
- CACNA1D | c.6259G>A p.E2087K (on ENST00000350061 / NM_001128840.3; = p.E2107K on NM_000720.4) | Missense Mutation (SNP) | VAF 132/649 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs762059527, COSV55436089, COSV55439012; called by muse, mutect2, varscan2
- CACNA2D1 | c.2038C>T p.L680F (on ENST00000356253 / NM_001366867.1; = p.L668F on NM_000722.4) | Missense Mutation (SNP) | VAF 242/386 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV62393667; called by muse, mutect2, varscan2
- CACNA2D4 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 215/384 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.337); catalogued as rs555700156, COSV54957400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADM2 | c.241C>T p.R81C (on ENST00000407528 / NM_001167674.2; = p.R83C on NM_153184.4) | Missense Mutation (SNP) | VAF 121/591 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs139991481, COSV67406856; called by muse, varscan2
- CAMK2A | c.1297C>T p.R433C (on ENST00000348628 / NM_171825.2; = p.R444C on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 346/571 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs767291853, COSV62245779; called by muse, varscan2
- CAMK2B | c.1700C>T p.S567L | Missense Mutation (SNP) | VAF 268/614 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as rs981667182, COSV99323036; called by muse, varscan2
- CAMSAP3 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 224/476 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs926396897; called by muse, varscan2
- CAPN10 | c.1217C>A p.S406* | Nonsense Mutation (SNP) | VAF 338/576 reads (59%) | catalogued as COSV54376964; called by muse, varscan2
- CAPN6 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 257/585 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60694486; called by muse, varscan2
- CARD11 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 162/733 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs1562490836, COSV67801341; called by muse, mutect2, varscan2
- CARMIL2 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 92/434 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as COSV58029732; called by muse, varscan2
- CARMIL2 | c.4121G>A p.R1374Q | Missense Mutation (SNP) | VAF 265/383 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as rs1372728652, COSV54667398; called by muse, mutect2, varscan2
- CASR | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 566/775 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.163); catalogued as rs201338034, COSV56137031; ClinVar: uncertain significance; called by muse, varscan2
- CASZ1 | c.4786G>A p.E1596K | Missense Mutation (SNP) | VAF 344/1240 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as COSV65458762; called by mutect2, varscan2
- CATSPERB | c.1743G>A p.G581= | Splice Region (SNP) | VAF 109/245 reads (44%) | catalogued as COSV99830736; called by muse, varscan2
- CATSPERB | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.167); catalogued as rs267604094, COSV56425352; called by muse, mutect2, varscan2
- CBL | c.1096-1G>A p.X366_splice | Splice Site (SNP) | VAF 55/62 reads (89%) | catalogued as CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; called by muse, mutect2, varscan2
- CBL | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 58/65 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1245863855, COSV50657369, COSV50665310; called by muse, mutect2, varscan2
- CCDC146 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 145/723 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV53551138; called by muse, mutect2, varscan2
- CCDC158 | c.2617C>T p.H873Y | Missense Mutation (SNP) | VAF 295/327 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772275545; called by muse, varscan2
- CCDC168 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 148/249 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0.303); catalogued as rs1206816544; called by muse, mutect2, varscan2
- CCDC85A | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 601/1118 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs764849312, COSV68154259; called by muse, varscan2
- CCDC88C | c.6049G>A p.D2017N | Missense Mutation (SNP) | VAF 311/871 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1251025859, COSV57796472; called by muse, varscan2
- CCKAR | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 314/512 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55164304; called by muse, varscan2
- CCNE1 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 201/324 reads (62%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.751); catalogued as COSV99388473; called by muse, mutect2, varscan2
- CD101 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 265/368 reads (72%) | catalogued as COSV56716421, COSV56717203; called by muse, mutect2, varscan2
- CD2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 99/613 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs1167182650, COSV65644093; called by muse, varscan2
- CD36 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 93/1240 reads (8%) | catalogued as rs139067066; called by muse, mutect2
- CD96 | c.1148C>T p.S383F (on ENST00000283285 / NM_198196.3; = p.S367F on NM_005816.5) | Missense Mutation (SNP) | VAF 97/428 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51913647; called by muse, mutect2, varscan2
- CDH23 | c.8896G>A p.D2966N | Missense Mutation (SNP) | VAF 490/668 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs767686501; called by muse, varscan2
- CDH9 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 260/693 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs267600596, COSV50253768; called by muse, mutect2, varscan2
- CDKL5 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 332/743 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV66111570; called by muse, mutect2, varscan2
- CEACAM1 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 229/339 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV50726571; called by muse, mutect2
- CEACAM20 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 287/449 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.16); catalogued as COSV57602979; called by muse, mutect2, varscan2
- CEP126 | c.2794C>T p.P932S | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.209); catalogued as COSV54828110; called by muse, varscan2
- CEP162 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 240/254 reads (94%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.563); catalogued as COSV57619647; called by muse, mutect2, varscan2
- CEP350 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 176/179 reads (98%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs765028602; called by muse, varscan2
- CFAP221 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 114/182 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as rs771543800, COSV99732217; called by muse, mutect2, varscan2
- CFAP43 | c.3373G>A p.G1125R | Missense Mutation (SNP) | VAF 84/361 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs139630636, COSV63852482; called by muse, mutect2, varscan2
- CFAP54 | c.8717T>A p.F2906Y | Missense Mutation (SNP) | VAF 115/221 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs878862938; called by muse, mutect2, varscan2
- CFHR1 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 150/171 reads (88%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV57628063; called by muse, mutect2, varscan2
- CFHR4 | c.308C>T p.S103F (on ENST00000367416 / NM_001201551.2; = p.S104F on NM_001201550.3) | Missense Mutation (SNP) | VAF 91/97 reads (94%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as rs1418071957, COSV52227339; called by muse, mutect2, varscan2
- CFTR | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 220/790 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as rs397508792, CM972940; called by muse, varscan2
- CFTR | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 61/382 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs766063304; called by muse, mutect2, varscan2
- CHD5 | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 150/843 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); catalogued as COSV52406711; called by muse, varscan2
- CHRDL1 | c.1126C>T p.R376* (on ENST00000372045; = p.R382* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 165/396 reads (42%) | catalogued as rs898698529, COSV54322916; called by muse, mutect2, varscan2
- CHRNA5 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183719313, COSV55137477; called by muse, mutect2, varscan2
- CHST8 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 537/788 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52858516; called by muse, varscan2
- CIC | c.4736C>T p.P1579L | Missense Mutation (SNP) | VAF 158/746 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99360434; called by muse, varscan2
- CLC | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 467/677 reads (69%) | catalogued as COSV99695566; called by muse, mutect2, varscan2
- CLCA2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 318/436 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377748354, COSV100991534; called by muse, mutect2
- CLDN8 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 200/448 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.198); catalogued as rs757114600, COSV54525792; called by muse, mutect2, varscan2
- CLEC17A | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.86); catalogued as rs764808677, COSV60426617; called by muse, varscan2
- CLIC3 | c.36G>A p.A12= | Splice Region (SNP) | VAF 298/322 reads (93%) | catalogued as rs1487684434; called by muse, mutect2, varscan2
- CLTCL1 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 194/788 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs781805918, COSV54238893; called by muse, varscan2
- CNKSR2 | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99669028; called by muse, mutect2, varscan2
- CNTN6 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1290051851, COSV63171333; called by muse, mutect2, varscan2
- CNTNAP4 | c.3014G>A p.G1005E | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.141); catalogued as COSV56674812; called by muse, mutect2, varscan2
- CNTNAP5 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 122/466 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs371834823, COSV70498646; called by muse, mutect2, varscan2
- COG8 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 112/542 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs974974225; called by muse, varscan2
- COL13A1 | c.521C>T p.P174L (on ENST00000398978 / NM_001130103.2; = p.P136L on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/508 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1333975031, COSV62569109, COSV62569645; called by muse, mutect2, varscan2
- COL22A1 | c.1091G>A p.W364* | Nonsense Mutation (SNP) | VAF 141/891 reads (16%) | catalogued as rs1399651606; called by muse, mutect2, varscan2
- COL4A2 | c.4291C>T p.R1431C | Missense Mutation (SNP) | VAF 104/350 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs139124960, COSV64626395; called by muse, varscan2
- COL6A3 | c.5378G>A p.S1793N | Missense Mutation (SNP) | VAF 199/610 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs886042944, COSV55078752; ClinVar: uncertain significance; called by muse, varscan2
- COL6A3 | c.4978C>T p.R1660C | Missense Mutation (SNP) | VAF 267/406 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1553556695, COSV55092173; ClinVar: uncertain significance; called by muse, varscan2
- COL6A3 | c.4649G>A p.G1550E | Missense Mutation (SNP) | VAF 161/514 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55078348; called by muse, mutect2, varscan2
- COL6A5 | c.6796G>A p.E2266K (on ENST00000312481; = p.E2262K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs1242504947, COSV55208131; called by muse, mutect2, varscan2
- COL6A6 | c.1923G>A p.M641I | Missense Mutation (SNP) | VAF 368/526 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV62025833; called by muse, mutect2, varscan2
- COL6A6 | c.4274G>A p.G1425E | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369345663; called by muse, varscan2
- COLEC12 | c.480C>G p.N160K | Missense Mutation (SNP) | VAF 515/869 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs199985975; called by muse, mutect2, varscan2
- CPAMD8 | c.1702C>T p.R568C (on ENST00000651564; = p.R521C on NM_015692.5) | Missense Mutation (SNP) | VAF 288/415 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs762584662, COSV52230795; called by muse, mutect2, varscan2
- CPNE2 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 134/604 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1283939208; called by muse, mutect2, varscan2
- CPT1C | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 120/558 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs376513063; called by muse, mutect2, varscan2
- CPVL | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 294/578 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs866569810; called by muse, varscan2
- CR1 | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 288/306 reads (94%) | SIFT tolerated (0.14); PolyPhen benign (0.375); catalogued as COSV100887649; called by muse, mutect2, varscan2
- CRB1 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 188/337 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.432); catalogued as COSV66334283; called by muse, mutect2, varscan2
- CRB2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 181/649 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as rs750735887; called by muse, mutect2, varscan2
- CREB3L3 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 114/478 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776820034, COSV50189294; called by muse, mutect2, varscan2
- CROCC | c.3797C>T p.T1266I | Missense Mutation (SNP) | VAF 736/946 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV65010966; called by muse, varscan2
- CSF1R | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 240/360 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs1221149937; called by muse, mutect2, varscan2
- CSMD1 | c.9332G>A p.G3111E (on ENST00000520002; = p.G3110E on NM_033225.6) | Missense Mutation (SNP) | VAF 109/558 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59338867; called by muse, varscan2
- CSMD1 | c.6062C>T p.S2021F (on ENST00000520002; = p.S2020F on NM_033225.6) | Missense Mutation (SNP) | VAF 254/356 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1456963597, COSV59327200; called by muse, mutect2, varscan2
- CSMD1 | c.3229C>T p.R1077C (on ENST00000520002; = p.R1076C on NM_033225.6) | Missense Mutation (SNP) | VAF 128/628 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867742507, COSV59279573, COSV59288383; called by muse, varscan2
- CSMD2 | c.4678G>A p.D1560N | Missense Mutation (SNP) | VAF 115/563 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99589625; called by muse, mutect2, varscan2
- CSPG4 | c.3382C>T p.R1128C | Missense Mutation (SNP) | VAF 192/684 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs765420925, COSV57893485; called by muse, varscan2
- CTNNA2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 244/490 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); catalogued as rs1444733248; called by muse, varscan2
- CUZD1 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 179/270 reads (66%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.916); catalogued as rs1321007301; called by muse, mutect2, varscan2
- CYP2C19 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as COSV64907584; called by muse, mutect2, varscan2
- CYP2C19 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV64909429; called by muse, mutect2, varscan2
- CYP2C9 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs780145404; called by muse, mutect2, varscan2
- CYP2D7 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 673/1411 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.571); catalogued as rs3171710, COSV100809518; called by muse, mutect2, varscan2
- CYP2J2 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 76/370 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1424304237; called by muse, varscan2
- CYP4F22 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 331/475 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751335732, COSV54107918; called by muse, mutect2, varscan2
- CYP7B1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 156/926 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866340497, COSV59582915; called by muse, varscan2
- CYSLTR1 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 235/556 reads (42%) | catalogued as rs866204187; called by muse, varscan2
- CYTIP | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 137/408 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51633051; called by muse, mutect2, varscan2
- DAB1 | c.1384C>T p.R462C (on ENST00000371231; = p.R429C on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 181/904 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1325593862; called by muse, mutect2, varscan2
- DAB2 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 358/999 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs758202197, COSV100297923; called by muse, mutect2, varscan2
- DCC | c.1753C>G p.L585V | Missense Mutation (SNP) | VAF 205/416 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.129); catalogued as COSV100498788; called by muse, mutect2, varscan2
- DCDC1 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 95/346 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as COSV100664171, COSV60848936; called by muse, mutect2, varscan2
- DCUN1D3 | c.377G>C p.R126P | Missense Mutation (SNP) | VAF 110/507 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as rs759576387, COSV100176743, COSV60952743; called by muse, mutect2, varscan2
- DDO | c.494G>A p.R165Q (on ENST00000368924 / NM_001368172.1; = p.R106Q on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 508/526 reads (97%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as rs779200242, COSV64470397; called by muse, varscan2
- DEFB116 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 82/393 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.185); catalogued as COSV101269208; called by muse, mutect2, varscan2
- DHRS7C | c.871C>T p.P291S (on ENST00000330255 / NM_001220493.2; = p.P290S on NM_001105571.3) | Missense Mutation (SNP) | VAF 659/694 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs957007375; called by muse, mutect2, varscan2
- DKK2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 254/288 reads (88%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs770400633, COSV53394433; called by muse, mutect2, varscan2
- DLEC1 | c.4315G>A p.E1439K | Missense Mutation (SNP) | VAF 73/487 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.225); catalogued as COSV57295156; called by muse, mutect2, varscan2
- DLL1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 928/969 reads (96%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as rs1243238981; called by muse, mutect2, varscan2
- DMD | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 116/292 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs761715369, COSV63739030; called by muse, mutect2, varscan2
- DMGDH | c.2267G>A p.G756E | Missense Mutation (SNP) | VAF 218/352 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54861171; called by muse, varscan2
- DNAH11 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV60961903; called by muse, mutect2, varscan2
- DNAH12 | c.3383C>T p.T1128M (on ENST00000351747; = p.T1151M on NM_001366028.2) | Missense Mutation (SNP) | VAF 65/374 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs372611509; called by muse, mutect2, varscan2
- DNAH17 | c.6691G>A p.E2231K | Missense Mutation (SNP) | VAF 130/826 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778357087; called by muse, varscan2
- DNAH5 | c.13775G>A p.R4592Q | Missense Mutation (SNP) | VAF 306/856 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367709427, COSV54253927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.12461C>T p.P4154L | Missense Mutation (SNP) | VAF 207/600 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs868750896; called by muse, mutect2, varscan2
- DNAH5 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 299/545 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54223750; called by muse, mutect2, varscan2
- DNAH6 | c.9415C>T p.L3139F | Missense Mutation (SNP) | VAF 207/342 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99404509; called by mutect2, varscan2
- DNAH8 | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as rs553578959, COSV59469912; called by muse, mutect2, varscan2
- DNAH8 | c.10282C>T p.L3428F | Missense Mutation (SNP) | VAF 154/465 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs1446285473; called by muse, varscan2
- DNAH9 | c.5777G>A p.R1926Q | Missense Mutation (SNP) | VAF 466/489 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs866019340; called by muse, varscan2
- DNAH9 | c.12074A>G p.N4025S | Missense Mutation (SNP) | VAF 424/454 reads (93%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.712); catalogued as rs772352224; called by muse, varscan2
- DNAJC18 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1393218973; called by muse, varscan2
- DOCK3 | c.5904G>A p.M1968I | Missense Mutation (SNP) | VAF 240/1078 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1247576945; called by muse, varscan2
- DOCK6 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 78/406 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs368164863; called by muse, mutect2, varscan2
- DOCK7 | c.3530C>T p.S1177F (on ENST00000635253 / NM_001367561.1; = p.S1146F on NM_033407.3) | Missense Mutation (SNP) | VAF 116/601 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1438314720; called by muse, mutect2, varscan2
- DOCK7 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 439/580 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs374515298, COSV52003536; called by muse, mutect2, varscan2
- DOK6 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 215/661 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101234532; called by muse, varscan2
- DPYD | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 316/426 reads (74%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100928980; called by muse, varscan2
- DRD4 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 188/488 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1305106318; called by mutect2, varscan2
- DSC3 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 146/414 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757290041, COSV64571675; called by muse, mutect2, varscan2
- DSCAML1 | c.2969C>T p.S990F (on ENST00000321322; = p.S930F on NM_020693.4) | Missense Mutation (SNP) | VAF 104/215 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1465069433, COSV58394347; called by muse, varscan2
- DSPP | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 188/312 reads (60%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.006); catalogued as COSV104390375; called by muse, varscan2
- DYDC1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 250/378 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs368866721; called by muse, varscan2
- DYM | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 203/492 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53987059; called by muse, varscan2
- EDRF1 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 373/521 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs745329281; called by muse, varscan2
- EEF2K | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 268/390 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs780264247; called by mutect2, varscan2
- EGFLAM | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 451/823 reads (55%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV59320213; called by muse, mutect2, varscan2
- EGFLAM | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 504/900 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100380645; called by muse, varscan2
- ELAVL4 | c.732C>T p.F244= | Splice Region (SNP) | VAF 76/517 reads (15%) | catalogued as COSV63918742; called by muse, varscan2
- EML6 | c.411G>A p.W137* | Nonsense Mutation (SNP) | VAF 278/474 reads (59%) | catalogued as rs1553385573; called by muse, varscan2
- ENPP4 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs775632459, COSV58090385; called by muse, mutect2, varscan2
- EPHB3 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 98/491 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV57807532; called by muse, mutect2, varscan2
- ERC2 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 73/395 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs751475951, COSV55609509; called by muse, mutect2, varscan2
- ERC2 | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 117/679 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs759704719, COSV55650368; called by muse, varscan2
- ERICH3 | c.3026C>T p.S1009L | Missense Mutation (SNP) | VAF 574/741 reads (77%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1365373663, COSV58605892; called by muse, mutect2, varscan2
- ERICH3 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 83/463 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745779160; called by muse, mutect2, varscan2
- ESX1 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 492/1194 reads (41%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.125); catalogued as rs1459875754; called by muse, varscan2
- EYS | c.7781G>A p.G2594E | Missense Mutation (SNP) | VAF 119/575 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV65475489; called by muse, mutect2, varscan2
- F13A1 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 610/984 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV53562917; called by muse, mutect2, varscan2
- FAIM2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 317/520 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs267603498, COSV57739214; called by muse, mutect2, varscan2
- FAM131B | c.-56G>A | Splice Region (SNP) | VAF 244/632 reads (39%) | catalogued as rs1445716572, COSV101281761; called by muse, mutect2, varscan2
- FAM131C | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 74/1100 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs1370207463; called by muse, mutect2
- FAM135B | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 158/719 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV99422191; called by muse, varscan2
- FAM171A1 | c.1217G>A p.G406D | Missense Mutation (SNP) | VAF 136/521 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs1160793865; called by muse, varscan2
- FAM3D | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 440/650 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV100716744; called by muse, varscan2
- FAM71B | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 89/276 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.099); catalogued as rs543304286, COSV57229990; called by muse, mutect2, varscan2
- FAM91A1 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV58235410; called by muse, mutect2, varscan2
- FATE1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 102/211 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV64848920, COSV64849094; called by muse, varscan2
- FBXO40 | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 85/405 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs147555575; called by muse, mutect2, varscan2
- FCRL4 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 301/318 reads (95%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV54860005, COSV99620480; called by muse, varscan2
- FCRL4 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 441/469 reads (94%) | SIFT tolerated (0.24); PolyPhen benign (0.261); catalogued as rs868440077; called by muse, mutect2, varscan2
- FERMT1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54090904; called by muse, mutect2, varscan2
- FGF18 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 158/530 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs756441926, COSV51127441; called by muse, mutect2, varscan2
- FHAD1 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 382/520 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs1044521497, COSV100119642; called by muse, mutect2, varscan2
- FILIP1 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 206/396 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52743247; called by muse, varscan2
- FIP1L1 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 270/298 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs760139823; called by muse, mutect2, varscan2
- FLG2 | c.6455G>A p.G2152E | Missense Mutation (SNP) | VAF 447/482 reads (93%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs138607426, COSV66171624; called by muse, mutect2, varscan2
- FLG2 | c.4840C>T p.H1614Y | Missense Mutation (SNP) | VAF 420/449 reads (94%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV66173685; called by muse, mutect2, varscan2
- FLNC | c.2317G>A p.G773R | Missense Mutation (SNP) | VAF 539/1674 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322212555; ClinVar: uncertain significance; called by muse, varscan2
- FLT1 | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 205/346 reads (59%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.742); catalogued as COSV56745835; called by muse, mutect2, varscan2
- FLT3 | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV54060926; called by muse, mutect2, varscan2
- FMO3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 256/286 reads (90%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as COSV63008738; called by mutect2, varscan2
- FSHB | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 220/372 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV54221544; called by muse, mutect2, varscan2
- FSHR | c.373C>T p.L125= | Splice Region (SNP) | VAF 158/440 reads (36%) | catalogued as COSV58617246; called by muse, mutect2, varscan2
- FTCD | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 148/750 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201753824, COSV52426509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FUT7 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 619/667 reads (93%) | SIFT tolerated (0.15); PolyPhen benign (0.309); catalogued as COSV55800479; called by muse, mutect2, varscan2
- FUT9 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 154/335 reads (46%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.755); catalogued as rs146406553, COSV56142363; called by muse, mutect2, varscan2
- FYB2 | c.1155G>A p.M385I | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs759460902, COSV58586953; called by muse, mutect2, varscan2
- GABRA2 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 213/231 reads (92%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV62916658; called by muse, varscan2
- GABRB3 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 161/424 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV54655540; called by muse, mutect2, varscan2
- GABRG1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 215/231 reads (93%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV54950313; called by muse, mutect2, varscan2
- GAL3ST1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 561/1230 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs764727999, COSV58892475; called by muse, mutect2, varscan2
- GALNTL6 | c.1042-1G>A p.X348_splice | Splice Site (SNP) | VAF 178/192 reads (93%) | catalogued as COSV72493747; called by muse, mutect2, varscan2
- GATA2 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 128/797 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as rs777726701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBP6 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 402/537 reads (75%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs142400726; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 85/357 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.984); catalogued as rs1394415998, COSV100374611; called by muse, mutect2, varscan2
- GFRAL | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 204/285 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV61229115; called by muse, varscan2
- GIMAP2 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 461/1079 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs141987826; called by muse, mutect2, varscan2
- GIMAP4 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 344/853 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs1352695671, COSV55432152; called by muse, mutect2, varscan2
- GIMAP6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 205/823 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs865805939, COSV61032437; called by muse, mutect2, varscan2
- GJB4 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 466/1324 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as rs773421859, COSV58357048; called by muse, varscan2
- GMNC | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 199/509 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV71249030; called by muse, mutect2, varscan2
- GOLGA6L7 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 192/600 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.38); catalogued as rs763513868, COSV101629716; called by muse, varscan2
- GPC4 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 135/332 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63698750; called by muse, varscan2
- GPR139 | c.509G>A p.W170* | Nonsense Mutation (SNP) | VAF 122/553 reads (22%) | catalogued as rs868806533, COSV100429930; called by muse, mutect2, varscan2
- GPR158 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 198/598 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs747693904, COSV66266831; called by muse, varscan2
- GPR61 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 149/807 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs565432681; called by muse, mutect2, varscan2
- GRAMD2A | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 106/376 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs999473779; called by muse, varscan2
- GREB1L | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 207/833 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as rs778569433; called by muse, varscan2
- GREB1L | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 66/648 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.4); catalogued as rs868440722; called by muse, mutect2, varscan2
- GRIA1 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 258/413 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53624114; called by muse, varscan2
- GRIN2B | c.3562G>A p.G1188S | Missense Mutation (SNP) | VAF 174/633 reads (27%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as rs367543149, COSV101662898; ClinVar: not provided; called by muse, mutect2
- GRIN2B | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 137/442 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV101663149; called by muse, mutect2, varscan2
- GRIPAP1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 209/466 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as COSV64552540; called by muse, varscan2
- GRM8 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 847/1380 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs143468706; called by muse, mutect2, varscan2
- GSG1L | c.397+1G>A p.X133_splice | Splice Site (SNP) | VAF 304/420 reads (72%) | catalogued as COSV66593464; called by muse, varscan2
- GSTA1 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 134/530 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1472380126, COSV58015073; called by muse, mutect2, varscan2
- GUCY2D | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 815/843 reads (97%) | SIFT tolerated (0.76); PolyPhen benign (0.017); catalogued as COSV54695107; called by muse, mutect2, varscan2
- HCN2 | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 204/262 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as rs1191857264; called by muse, varscan2
- HDGFL1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 861/1431 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs765436695; called by muse, varscan2
- HFM1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 193/278 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs199692136; called by muse, mutect2, varscan2
- HHIP | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 298/320 reads (93%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs369873424; called by muse, varscan2
- HIF3A | c.1573C>T p.R525W (on ENST00000377670 / NM_152795.4; = p.R456W on NM_022462.4) | Missense Mutation (SNP) | VAF 218/923 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs148799051; called by muse, varscan2
- HIPK1 | c.577T>A p.L193M | Missense Mutation (SNP) | VAF 108/622 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65782991; called by muse, mutect2, varscan2
- HMGCLL1 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 72/426 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51451651; called by muse, mutect2, varscan2
- HNF4A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 196/437 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.444); catalogued as rs748452860, COSV57382487; called by muse, mutect2, varscan2
- HNRNPR | c.55A>G p.M19V | Missense Mutation (SNP) | VAF 104/592 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs758506054; called by muse, mutect2, varscan2
- HS3ST4 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 349/509 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367931100, COSV100499854; called by muse, mutect2, varscan2
- HSD17B2 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 111/531 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.392); catalogued as rs779171937, COSV52274204; called by muse, varscan2
- HTR1A | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 160/574 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1403228466, COSV60501438, COSV60502125; called by muse, varscan2
- HTR3A | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 136/323 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs867161218, COSV100248571; called by muse, varscan2
- HUS1B | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 180/1080 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs867882133; called by muse, varscan2
- HYDIN | c.6394G>A p.E2132K | Missense Mutation (SNP) | VAF 254/363 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0.359); catalogued as rs373417090; called by muse, mutect2, varscan2
- IFIT2 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 199/291 reads (68%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1224127615; called by muse, mutect2, varscan2
- IFNG | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 238/368 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs377736305; called by muse, varscan2
- IFT140 | c.3568G>A p.E1190K | Missense Mutation (SNP) | VAF 499/692 reads (72%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs752576154; called by muse, mutect2, varscan2
- IGKV1-5 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 458/842 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as rs773635617; called by muse, varscan2
- IGKV4-1 | c.100T>C p.S34P | Missense Mutation (SNP) | VAF 300/531 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs72847567; called by muse, mutect2, varscan2
- IL1RAPL1 | c.750T>G p.S250R | Missense Mutation (SNP) | VAF 132/289 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1402973430; called by muse, mutect2, varscan2
- IL20RA | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 246/591 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as rs138424318; called by muse, mutect2, varscan2
- IL27 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 102/497 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as rs1246707653; called by muse, varscan2
- IL36B | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52084330; called by muse, mutect2, varscan2
- IL37 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 76/358 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1489179993; called by muse, varscan2
- IL7R | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 580/1068 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV57406297, COSV57407283; called by muse, mutect2, varscan2
- INPP5F | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 309/450 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs775757691, COSV62820590, COSV62821584; called by muse, varscan2
- INSYN2A | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 402/824 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs143223796; called by muse, varscan2
- IQCJ | c.374G>A p.R125K | Missense Mutation (SNP) | VAF 361/543 reads (66%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1436503993; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 86/576 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs758844693; called by muse, mutect2, varscan2
- IRAK1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 117/594 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1557129491; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.781A>G p.M261V | Missense Mutation (SNP) | VAF 331/491 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.219); catalogued as rs749056720, COSV99860806; called by muse, mutect2, varscan2
- ITGA10 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.358); catalogued as COSV65196112; called by muse, mutect2, varscan2
- ITGA2B | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 239/548 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1210956482, COSV52232893; called by muse, mutect2, varscan2
- ITGAL | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 175/313 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV63320430; called by muse, mutect2, varscan2
- ITIH5 | c.1416C>T p.I472= | Splice Region (SNP) | VAF 149/229 reads (65%) | catalogued as rs910753360, COSV99906272; called by muse, mutect2, varscan2
- ITK | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 137/219 reads (63%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV70065191; called by muse, mutect2, varscan2
- ITPRIP | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 422/602 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs780957842, COSV53393198; called by muse, varscan2
- ITSN2 | c.601G>C p.G201R | Missense Mutation (SNP) | VAF 156/450 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.958); catalogued as rs754963285; called by muse, mutect2, varscan2
- JADE2 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 156/248 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99253725; called by muse, mutect2, varscan2
- KCNA3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 168/911 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1238509684; called by muse, mutect2, varscan2
- KCNB2 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 162/1034 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050367; called by muse, varscan2
- KCNG4 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 554/710 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759093264, COSV57584090; called by muse, varscan2
- KCNH5 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 174/361 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100527372; called by muse, varscan2
- KCNH7 | c.2702G>A p.G901E | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV59804554; called by muse, varscan2
- KCNN1 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 210/1042 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs749961468; called by muse, varscan2
- KCNQ3 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 96/459 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV66475740; called by muse, mutect2, varscan2
- KDM6A | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 109/518 reads (21%) | catalogued as COSV65038913, COSV65040651; called by muse, mutect2, varscan2
- KIF2B | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 324/725 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV52136156; called by muse, mutect2, varscan2
- KIF6 | c.399+1G>A p.X133_splice | Splice Site (SNP) | VAF 234/362 reads (65%) | catalogued as rs771821721, COSV99757212; called by muse, mutect2, varscan2
- KIF7 | c.1022A>G p.N341S | Missense Mutation (SNP) | VAF 233/762 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs757699508; called by muse, varscan2
- KIR2DL3 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 184/584 reads (32%) | catalogued as rs754862541, COSV60897196; called by muse, mutect2
- KLF10 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 136/951 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV53436220; called by muse, mutect2, varscan2
- KLHL3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 110/418 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as rs976865705; called by muse, varscan2
- KLK1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 164/698 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100032766; called by muse, varscan2
- KLK2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 281/657 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV100320049; called by muse, mutect2, varscan2
- KLRF1 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54380769; called by muse, varscan2
- KMT2D | c.13363C>T p.R4455C | Missense Mutation (SNP) | VAF 192/624 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs530054198; called by muse, mutect2, varscan2
- KMT5C | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 72/292 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs764360208, COSV55318969; called by muse, mutect2, varscan2
- KRT27 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 232/506 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs762368035; called by muse, varscan2
- KRT32 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 324/344 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99862956; called by muse, mutect2, varscan2
- KSR1 | c.571G>A p.E191K (on ENST00000644974 / NM_001367810.1; = p.E54K on NM_014238.2) | Missense Mutation (SNP) | VAF 746/793 reads (94%) | SIFT tolerated (0.24); PolyPhen benign (0.272); catalogued as rs764032318; called by muse, mutect2, varscan2
- KYNU | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 112/213 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as COSV51585309; called by muse, mutect2, varscan2
- LAMA1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 209/574 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101057260; called by muse, mutect2, varscan2
- LAMA2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 390/413 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70337829, COSV70345955; called by muse, mutect2, varscan2
- LAMA2 | c.4496G>A p.R1499Q | Missense Mutation (SNP) | VAF 415/434 reads (96%) | SIFT tolerated (0.56); PolyPhen benign (0.325); catalogued as rs375100782; called by muse, varscan2
- LCORL | c.4945C>T p.P1649S | Missense Mutation (SNP) | VAF 76/330 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs1404782247; called by muse, varscan2
- LEPR | c.2004G>A p.M668I | Missense Mutation (SNP) | VAF 222/310 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV60759035; called by muse, mutect2, varscan2
- LGR6 | c.1442C>T p.P481L (on ENST00000367278 / NM_001017403.1; = p.P429L on NM_021636.3) | Missense Mutation (SNP) | VAF 358/380 reads (94%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1373153177; called by muse, varscan2
- LHCGR | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 143/467 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54296277; called by muse, mutect2, varscan2
- LIFR | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 452/816 reads (55%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.834); catalogued as COSV54693785; called by muse, varscan2
- LILRA4 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 557/844 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52493768; called by muse, varscan2
- LILRB5 | c.1567G>A p.E523K (on ENST00000449561 / NM_001081442.3; = p.E522K on NM_006840.5) | Missense Mutation (SNP) | VAF 146/738 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100300940; called by muse, varscan2
- LMAN1L | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 324/521 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1490407403, COSV100547563, COSV59000516; called by muse, varscan2
- LMO7 | c.2482C>T p.P828S (on ENST00000357063; = p.P509S on NM_005358.5) | Missense Mutation (SNP) | VAF 278/457 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV58548693; called by muse, mutect2, varscan2
- LONRF3 | c.1541C>T p.S514L (on ENST00000371628 / NM_001031855.3; = p.S473L on NM_024778.5) | Missense Mutation (SNP) | VAF 97/239 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.179); catalogued as COSV59151998; called by muse, mutect2, varscan2
- LPAR4 | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 129/601 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.295); catalogued as COSV101425177; called by muse, mutect2, varscan2
- LRFN2 | c.2078C>T p.S693L | Missense Mutation (SNP) | VAF 226/1500 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as rs369739868; called by muse, mutect2, varscan2
- LRP2 | c.13858C>T p.P4620S | Missense Mutation (SNP) | VAF 130/448 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55554203; called by muse, mutect2, varscan2
- LRP2 | c.12397G>A p.E4133K | Missense Mutation (SNP) | VAF 290/500 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV55566677; called by muse, mutect2, varscan2
- LRRC1 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 211/697 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63828325; called by muse, mutect2, varscan2
- LRRC17 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 74/1412 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV50866822; called by muse, mutect2
- LY75 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.026); catalogued as COSV55112579; called by muse, mutect2, varscan2
- M1AP | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 209/632 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV51844822; called by muse, varscan2
- MAG | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 184/893 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.415); catalogued as rs1476187963, COSV100727966; called by muse, varscan2
- MAGEB16 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 404/887 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.069); catalogued as rs746408660; called by muse, varscan2
- MAGEB18 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 104/438 reads (24%) | catalogued as rs1569246703; called by muse, mutect2, varscan2
- MAGEC1 | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 191/810 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV53577923, COSV53580970; called by muse, mutect2, varscan2
- MAGED2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 241/562 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99514607; called by muse, mutect2, varscan2
- MAGEE1 | c.2195C>T p.S732F | Missense Mutation (SNP) | VAF 158/720 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs1325796028; called by muse, varscan2
- MAGEL2 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 484/860 reads (56%) | SIFT deleterious, low confidence (0); catalogued as rs183812337, COSV58568463; called by muse, varscan2
- MAPK4 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 271/1024 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.558); catalogued as rs761581511, COSV68542087; called by muse, mutect2, varscan2
- MCF2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1267860187, COSV100644973, COSV58480427; called by muse, mutect2, varscan2
- MCF2L | c.1112C>T p.S371F (on ENST00000375608; = p.S339F on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/357 reads (28%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.616); catalogued as COSV65050664; called by muse, mutect2, varscan2
- MEGF8 | c.5776C>T p.R1926* (on ENST00000251268 / NM_001271938.2; = p.R1859* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 506/768 reads (66%) | catalogued as COSV52101755; called by muse, varscan2
- MET | c.2402G>A p.C801Y | Missense Mutation (SNP) | VAF 846/1261 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV59257645; called by muse, varscan2
- MGAM | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 255/501 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as COSV72073548; called by muse, mutect2, varscan2
- MGAM2 | c.4012C>T p.P1338S | Missense Mutation (SNP) | VAF 154/939 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351550217; called by muse, mutect2, varscan2
- MKRN3 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 180/562 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV58809034; called by muse, mutect2, varscan2
- MME | c.1915-1G>A p.X639_splice | Splice Site (SNP) | VAF 169/244 reads (69%) | catalogued as COSV64710727; called by muse, mutect2, varscan2
- MME | c.2154G>A p.R718= | Splice Region (SNP) | VAF 62/348 reads (18%) | catalogued as COSV64706287; called by muse, varscan2
- MMP23B | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 116/714 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1435936760; called by muse, varscan2
- MMP28 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 469/505 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1033215349; called by muse, varscan2
- MMP7 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 128/254 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1010094931; called by muse, varscan2
- MOG | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 394/1241 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs376255591; called by muse, varscan2
- MORF4L2 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 357/753 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs763870312; called by muse, mutect2, varscan2
- MOV10L1 | c.3068G>A p.G1023D | Missense Mutation (SNP) | VAF 337/796 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748978745; called by muse, mutect2, varscan2
- MRC2 | c.2700C>T p.F900= | Splice Region (SNP) | VAF 396/892 reads (44%) | catalogued as COSV57645646; called by muse, varscan2
- MRC2 | c.3814C>T p.P1272S | Missense Mutation (SNP) | VAF 467/973 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as COSV57641589; called by muse, mutect2, varscan2
- MRGPRX1 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 261/734 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1368499311, COSV57107436; called by muse, varscan2
- MROH2B | c.3874G>A p.E1292K | Missense Mutation (SNP) | VAF 331/635 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV68183148; called by muse, varscan2
- MRTFA | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 432/853 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs772930139, COSV62931401, COSV62932866; called by muse, varscan2
- MSH4 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as COSV54197607; called by muse, varscan2
- MUC16 | c.32026G>A p.E10676K | Missense Mutation (SNP) | VAF 348/496 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as COSV67491904; called by muse, varscan2
- MUC16 | c.29087G>A p.G9696E | Missense Mutation (SNP) | VAF 126/576 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV67482472; called by muse, mutect2, varscan2
- MUC16 | c.29086G>A p.G9696R | Missense Mutation (SNP) | VAF 128/574 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.042); catalogued as COSV67467789; called by muse, mutect2, varscan2
- MUC16 | c.22012G>A p.E7338K | Missense Mutation (SNP) | VAF 323/457 reads (71%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.027); catalogued as COSV67481394; called by muse, mutect2, varscan2
- MUC16 | c.11686G>T p.E3896* | Nonsense Mutation (SNP) | VAF 117/568 reads (21%) | catalogued as COSV67456265, COSV67475926; called by muse, mutect2, varscan2
- MUC16 | c.3683C>T p.S1228L | Missense Mutation (SNP) | VAF 283/642 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs778561167, COSV67465815; called by muse, mutect2, varscan2
- MUC16 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 104/500 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101198439, COSV67470021; called by muse, mutect2, varscan2
- MUC17 | c.2888C>T p.S963L | Missense Mutation (SNP) | VAF 168/2569 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs1371676392, COSV60281001; called by muse, mutect2
- MUC4 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 812/1107 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs112809413; called by muse, mutect2, varscan2
- MUC6 | c.3034G>A p.D1012N | Missense Mutation (SNP) | VAF 218/850 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762847721; called by muse, varscan2
- MUL1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs1421654305; called by muse, mutect2, varscan2
- MYCBPAP | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 397/874 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100089296; called by muse, varscan2
- MYH15 | c.2776C>T p.Q926* | Nonsense Mutation (SNP) | VAF 508/704 reads (72%) | catalogued as rs1443942160; called by muse, varscan2
- MYH4 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 624/651 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55117438; called by muse, mutect2, varscan2
- MYH7 | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 188/506 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62520880; called by muse, mutect2, varscan2
- MYO16 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV51788523; called by muse, mutect2, varscan2
- MYO16 | c.3863G>A p.S1288N | Missense Mutation (SNP) | VAF 263/822 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs1344542223, COSV62757539; called by muse, varscan2
- MYOCD | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 428/463 reads (92%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs774560419, COSV58513540; called by muse, mutect2, varscan2
- NAA60 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 62/320 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472076803, COSV100692879; called by muse, mutect2, varscan2
- NAP1L4 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV65882197, COSV65882413; called by muse, mutect2, varscan2
- NCOA6 | c.2962C>T p.P988S | Missense Mutation (SNP) | VAF 446/655 reads (68%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.091); catalogued as COSV62864438, COSV62868209; called by muse, varscan2
- NELL2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 142/443 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs369537621; called by muse, varscan2
- NEUROD4 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 158/497 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs774478814, COSV54474018; called by muse, mutect2, varscan2
- NEXMIF | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 242/515 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV50057480; called by muse, mutect2, varscan2
- NFAM1 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 426/909 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV61195448; called by muse, mutect2, varscan2
- NFATC1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 561/1530 reads (37%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.919); catalogued as rs765526389; called by muse, mutect2
- NFATC4 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 234/1287 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs747668845, COSV51609189; called by muse, varscan2
- NGEF | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 108/381 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs143001761; called by muse, mutect2, varscan2
- NHS | c.564G>A p.V188= | Splice Region (SNP) | VAF 268/563 reads (48%) | catalogued as rs368497497; called by muse, varscan2
- NLGN4X | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 215/512 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52011777, COSV52036003; called by muse, mutect2, varscan2
- NLRC3 | c.2601G>A p.L867= | Splice Region (SNP) | VAF 254/367 reads (69%) | catalogued as COSV57088083; called by muse, mutect2, varscan2
- NLRP4 | c.1487G>A p.W496* | Nonsense Mutation (SNP) | VAF 391/564 reads (69%) | catalogued as COSV56712791; called by muse, varscan2
- NLRP9 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 374/535 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs759340206, COSV60461331; called by muse, varscan2
- NOS3 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 311/1162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52492127; called by muse, mutect2, varscan2
- NOVA1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 444/822 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57486207; called by muse, varscan2
- NPPB | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 128/691 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV64687567; called by muse, mutect2, varscan2
- NPR2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 567/598 reads (95%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV61313665; called by muse, varscan2
- NPY5R | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 124/205 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV58452571; called by muse, mutect2, varscan2
- NREP | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 217/351 reads (62%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1192701096, COSV67401246; called by muse, varscan2
- NRG1 | c.242C>T p.P81L (on ENST00000523534; = p.P228L on NM_013962.2) | Missense Mutation (SNP) | VAF 415/620 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1401083340; called by muse, mutect2, varscan2
- NRP1 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 117/446 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1376849398; called by muse, varscan2
- NXPH1 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 243/527 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101339580; called by muse, mutect2, varscan2
- NXPH3 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 150/526 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165582; called by muse, mutect2, varscan2
- OBSCN | c.20249C>T p.S6750F | Missense Mutation (SNP) | VAF 327/350 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62367518; called by muse, varscan2
- OCRL | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853855, CM002075; ClinVar: not provided; called by muse, mutect2, varscan2
- OGDHL | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 86/404 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370076789; called by muse, varscan2
- OGDHL | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 97/437 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV65100576; called by muse, mutect2, varscan2
- OLR1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs267603272; called by muse, mutect2, varscan2
- OPRK1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 156/970 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV55569167; called by muse, mutect2, varscan2
- OR10AG1 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 220/361 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56635235; called by muse, mutect2, varscan2
- OR10G8 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 293/324 reads (90%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV70909429; called by muse, varscan2
- OR10G9 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 154/580 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs1206441063, COSV100901436; called by muse, varscan2
- OR10W1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 107/356 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV67720794; called by muse, mutect2
- OR14C36 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1351356830, COSV58601692; called by muse, mutect2, varscan2
- OR2A2 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 323/1274 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761285796; called by muse, mutect2, varscan2
- OR2AJ1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 124/389 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs866152293; called by muse, mutect2, varscan2
- OR2T12 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 515/562 reads (92%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV58775820; called by muse, mutect2, varscan2
- OR4A47 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 258/390 reads (66%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.09); catalogued as rs367667078; called by muse, varscan2
- OR4A5 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs570062308, COSV100157166; called by muse, mutect2, varscan2
- OR4C6 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 108/382 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.323); catalogued as COSV58604690, COSV58606437; called by muse, varscan2
- OR4D2 | c.801G>A p.M267I | Missense Mutation (SNP) | VAF 422/958 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV73459859; called by muse, varscan2
- OR4E2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 143/369 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV57731425; called by muse, mutect2, varscan2
- OR4F6 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 216/483 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as rs1461540396, COSV61026980; called by muse, mutect2, varscan2
- OR5B12 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 250/389 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.029); catalogued as COSV56905030, COSV56906809; called by muse, mutect2, varscan2
- OR5D13 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 111/357 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs867480738, COSV100686785; called by muse, mutect2, varscan2
- OR6N1 | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 211/232 reads (91%) | catalogued as COSV58650273; called by muse, mutect2, varscan2
- OR8J3 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 130/225 reads (58%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV56882367; called by muse, mutect2, varscan2
- OSBPL3 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 167/381 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs779397050; called by muse, mutect2, varscan2
- OTOGL | c.5077G>A p.D1693N (on ENST00000547103; = p.D1684N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764302483, COSV54015194, COSV54018068; called by muse, mutect2, varscan2
- OTOGL | c.5260G>A p.D1754N (on ENST00000547103; = p.D1745N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/150 reads (66%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1429518056; called by muse, mutect2, varscan2
- PACS2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 294/554 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV57655992; called by muse, mutect2, varscan2
- PADI4 | c.1802C>G p.P601R | Missense Mutation (SNP) | VAF 322/462 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64924071; called by muse, varscan2
- PARP8 | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 110/421 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99892335; called by muse, varscan2
- PARP8 | c.2197C>T p.L733F | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); catalogued as rs1281381538; called by muse, varscan2
- PASD1 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 377/873 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV64855689; called by muse, mutect2, varscan2
- PBRM1 | c.4960A>G p.K1654E (on ENST00000296302 / NM_001366071.2; = p.K1547E on NM_018313.5) | Missense Mutation (SNP) | VAF 523/693 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.396); catalogued as COSV56290572; called by muse, mutect2, varscan2
- PCDH15 | c.3009G>A p.K1003= | Splice Region (SNP) | VAF 100/143 reads (70%) | catalogued as rs1478490847; called by muse, mutect2, varscan2
- PCDH15 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 124/522 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs192813057, COSV57279849; ClinVar: uncertain significance; called by muse, varscan2
- PCDH15 | c.1645C>T p.L549F | Missense Mutation (SNP) | VAF 117/512 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV57312185, COSV57372906; called by muse, mutect2, varscan2
- PCDH8 | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 550/867 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58811305; called by muse, varscan2
- PCDHA2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 148/231 reads (64%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.147); catalogued as rs17844246, COSV65366110; called by muse, mutect2, varscan2
- PCDHGB3 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 216/794 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54030946; called by muse, varscan2
- PCLO | c.11477G>A p.G3826E | Missense Mutation (SNP) | VAF 316/1410 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61653210, COSV61660273; called by muse, mutect2, varscan2
- PCLO | c.4630G>A p.E1544K | Missense Mutation (SNP) | VAF 265/1156 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV61656062; called by muse, mutect2, varscan2
- PCNX2 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 276/456 reads (61%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.017); catalogued as rs181942130; called by muse, mutect2, varscan2
- PCP4L1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 267/284 reads (94%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as rs1253772768, COSV73440577; called by muse, mutect2, varscan2
- PDE1A | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 125/206 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs760883561; called by muse, mutect2, varscan2
- PDLIM1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 132/540 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.342); catalogued as COSV61473837; called by muse, varscan2
- PDXDC1 | c.1906G>A p.G636R | Missense Mutation (SNP) | VAF 144/723 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765071919; called by muse, mutect2, varscan2
- PELI1 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 228/635 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62730337; called by muse, mutect2, varscan2
- PGC | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 496/812 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768314678, COSV63123835; called by muse, varscan2
- PHC2 | c.168del p.V57Cfs*3 | Frame Shift Del (DEL) | VAF 67/395 reads (17%) | catalogued as COSV57106610; called by mutect2, pindel, varscan2
- PHETA1 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 441/706 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs778775900; called by muse, mutect2, varscan2
- PHEX | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 67/343 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV65079438; called by muse, mutect2, varscan2
- PHF20 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 209/304 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs746538790; called by muse, varscan2
- PHKA1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 227/525 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59804362; called by muse, mutect2, varscan2
- PI16 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 96/791 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.532); catalogued as rs749242578, COSV65447997, COSV65448409; called by muse, mutect2, varscan2
- PIEZO2 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 201/738 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs898421844; called by muse, mutect2, varscan2
- PIK3C2G | c.4400G>A p.R1467Q (on ENST00000676171; = p.R1426Q on NM_004570.5) | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767127006; called by muse, mutect2, varscan2
- PITX1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 196/338 reads (58%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs748627311; called by muse, varscan2
- PKD1 | c.3818C>T p.T1273I | Missense Mutation (SNP) | VAF 598/871 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs933551615; called by muse, varscan2
- PKD1L1 | c.8492C>T p.P2831L | Missense Mutation (SNP) | VAF 191/473 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs1358665703; called by muse, mutect2, varscan2
- PKD1L3 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 121/165 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371937366; called by muse, mutect2, varscan2
- PKP2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 336/530 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as COSV50731382; called by muse, varscan2
- PLAC1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 141/788 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs200146015, COSV63656850; called by muse, mutect2, varscan2
- PLCB1 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1364886743, COSV62042906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCG2 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 76/466 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.181); catalogued as rs770601419, COSV100842743, COSV63869239, COSV63873402; called by muse, mutect2, varscan2
- PLCL2 | c.985G>A p.E329K (on ENST00000615277 / NM_001144382.2; = p.E203K on NM_015184.5) | Missense Mutation (SNP) | VAF 254/360 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.271); catalogued as COSV67624935; called by muse, mutect2, varscan2
- PLCZ1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 140/274 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.13); catalogued as COSV56854309; called by muse, varscan2
- PLEKHA6 | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 260/297 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55340245; called by muse, mutect2, varscan2
- PLEKHN1 | c.1643C>T p.P548L (on ENST00000379409; = p.P496L on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/1176 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV58022597; called by muse, varscan2
- PLXNB3 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 545/1182 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV62795753; called by muse, varscan2
- PODN | c.274G>A p.E92K (on ENST00000395871; = p.E44K on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 934/1247 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as rs769165495, COSV57010995; called by muse, varscan2
- POF1B | c.726G>A p.V242= | Splice Region (SNP) | VAF 142/304 reads (47%) | catalogued as rs879091306, COSV99427446; called by muse, varscan2
- POMGNT2 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 279/705 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1034936858; called by muse, mutect2, varscan2
- PPFIA2 | c.835A>G p.K279E | Missense Mutation (SNP) | VAF 214/318 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV61020153; called by muse, mutect2, varscan2
- PPFIA2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 96/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61030769; called by muse, mutect2, varscan2
- PPIA | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); catalogued as rs1164610556, COSV63534314; called by muse, mutect2, varscan2
- PPM1J | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 474/657 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as rs775583142; called by mutect2, varscan2
- PPP1R13L | c.2357C>T p.T786I | Missense Mutation (SNP) | VAF 420/904 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100714778; called by muse, mutect2, varscan2
- PPP1R14C | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 325/343 reads (95%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs766379125, COSV100744829, COSV63173202; called by muse, mutect2, varscan2
- PPP1R3A | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 283/1216 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV52889819, COSV99493725; called by muse, mutect2, varscan2
- PRAMEF1 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 176/982 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs369455721; called by muse, mutect2
- PRAMEF11 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 122/1183 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV101463416; called by muse, varscan2
- PRKCI | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99856058; called by muse, mutect2, varscan2
- PRKN | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 478/508 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1404458540; called by muse, varscan2
- PROM2 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 184/608 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751957720, COSV100468915; called by muse, varscan2
- PSG2 | c.543G>A p.W181* | Nonsense Mutation (SNP) | VAF 130/601 reads (22%) | catalogued as COSV61545792; called by muse, mutect2, varscan2
- PSG6 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 301/421 reads (71%) | catalogued as rs1299318377; called by muse, mutect2, varscan2
- PSKH2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 1116/1401 reads (80%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV52609635; called by muse, varscan2
- PSMD2 | c.1986G>T p.M662I | Missense Mutation (SNP) | VAF 136/660 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs781306544; called by muse, varscan2
- PTPN22 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 177/242 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63086374; called by mutect2, varscan2
- PTPRB | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 115/394 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54250520; called by muse, varscan2
- PTPRB | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 104/320 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); catalogued as COSV99718708; called by muse, mutect2, varscan2
- PTPRK | c.3526G>A p.E1176K (on ENST00000368215 / NM_001291984.2; = p.E1177K on NM_002844.4) | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63890744, COSV63895574; called by muse, varscan2
- PTPRQ | c.1916G>A p.G639E (on ENST00000616559; = p.G597E on NM_001145026.2) | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57044347; called by muse, varscan2
- PTPRQ | c.4534C>T p.R1512C (on ENST00000616559; = p.R1470C on NM_001145026.2) | Missense Mutation (SNP) | VAF 168/287 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs769414150, COSV57044324; called by muse, mutect2, varscan2
- PTPRT | c.3796G>A p.D1266N | Missense Mutation (SNP) | VAF 392/568 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779663880, COSV61962183; called by muse, mutect2, varscan2
- PTPRZ1 | c.6590C>T p.P2197L | Missense Mutation (SNP) | VAF 318/637 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs759137152; called by muse, varscan2
- PXDNL | c.4316C>T p.P1439L | Missense Mutation (SNP) | VAF 112/642 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs1345639960, COSV100685712, COSV100687045; called by muse, mutect2
- PXDNL | c.1843C>G p.L615V | Missense Mutation (SNP) | VAF 88/633 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1460757004, COSV62494809; called by muse, mutect2, varscan2
- RAD51AP2 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 120/393 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV67588482; called by muse, mutect2, varscan2
- RANBP3L | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 246/623 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs773106667; called by muse, varscan2
- RASGRP4 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 325/487 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1400890346; called by muse, mutect2, varscan2
- RBBP6 | c.4297C>T p.R1433C | Missense Mutation (SNP) | VAF 228/317 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as rs1490786927, COSV60503810; called by muse, varscan2
- RBPJL | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 124/610 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.564); catalogued as COSV59212775; called by muse, varscan2
- RBSN | c.1325G>C p.G442A | Missense Mutation (SNP) | VAF 552/759 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53795003; called by muse, mutect2, varscan2
- RELN | c.7387C>T p.P2463S | Missense Mutation (SNP) | VAF 222/1659 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs865938622; called by muse, mutect2, varscan2
- RET | c.3145C>T p.P1049S | Missense Mutation (SNP) | VAF 131/677 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100394920; called by muse, mutect2, varscan2
- RHCE | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 491/671 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV53802074; called by muse, mutect2, varscan2
- RICTOR | c.3077C>T p.S1026L | Missense Mutation (SNP) | VAF 278/781 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs752956118; called by muse, mutect2, varscan2
- RLIM | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 306/699 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs778391559; called by muse, mutect2, varscan2
- RNF123 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 81/347 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV59691146; called by muse, mutect2, varscan2
- RNF180 | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 131/220 reads (60%) | catalogued as rs770108803; called by muse, mutect2, varscan2
- RNF217 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 792/838 reads (95%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV101451395; called by muse, mutect2, varscan2
- RP1 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs749195619, COSV104377682; called by muse, mutect2, varscan2
- RP1 | c.4627G>A p.D1543N | Missense Mutation (SNP) | VAF 253/355 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV55116509; called by muse, mutect2, varscan2
- RP2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 125/297 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs782721235, COSV54462553; ClinVar: benign; called by muse, mutect2, varscan2
- RPAP1 | c.3670G>A p.G1224R | Missense Mutation (SNP) | VAF 257/438 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377451240; called by muse, varscan2
- RPE65 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs748546353, COSV52013547, COSV52015838, COSV52016741; called by muse, mutect2, varscan2
- RPS6KA2 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 323/335 reads (96%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs1198195311, COSV55815902; called by muse, mutect2, varscan2
- RPTN | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 174/535 reads (33%) | catalogued as COSV100285868; called by muse, mutect2, varscan2
- RTL1 | c.2683G>A p.D895N | Missense Mutation (SNP) | VAF 343/849 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs561955511, COSV66017312; called by muse, mutect2, varscan2
- RTN1 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 234/458 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV50718640; called by muse, mutect2, varscan2
- RTN4R | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 755/1696 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs764343548, COSV50381942; called by muse, varscan2
- RUNX1 | c.1028C>T p.A343V (on ENST00000344691 / NM_001001890.3; = p.A370V on NM_001754.5) | Missense Mutation (SNP) | VAF 204/966 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs1457932375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RXFP2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs267603799; called by muse, mutect2, varscan2
- RXFP2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 156/259 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243388453, COSV53637789; called by muse, mutect2, varscan2
- RYR3 | c.2457G>A p.M819I | Missense Mutation (SNP) | VAF 128/452 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.239); catalogued as COSV66809818; called by muse, mutect2, varscan2
- RYR3 | c.10181C>T p.S3394L (on ENST00000389232; = p.S3395L on NM_001036.6) | Missense Mutation (SNP) | VAF 156/309 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1442312090, COSV66803668; called by muse, mutect2, varscan2
- S100A7L2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 184/318 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs943172702, COSV100906869, COSV64194894; called by muse, varscan2
- SALL3 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 152/383 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs937827552; called by muse, mutect2, varscan2
- SAMD7 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 64/382 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.18); catalogued as COSV59416739; called by muse, mutect2, varscan2
- SAMD9L | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 373/740 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100560676; called by muse, mutect2, varscan2
- SCAND1 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 185/890 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1184291076; called by muse, varscan2
- SCAP | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 274/404 reads (68%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs1052387428; called by muse, varscan2
- SCARA5 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 118/544 reads (22%) | catalogued as rs1022788310, COSV57276036; called by muse, varscan2
- SCG3 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 141/240 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs539392045; called by muse, varscan2
- SCN10A | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 420/606 reads (69%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV71861376; called by muse, mutect2
- SCN11A | c.5011G>A p.D1671N | Missense Mutation (SNP) | VAF 118/619 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs767489166; called by muse, mutect2, varscan2
- SCN4A | c.2286G>A p.W762* | Nonsense Mutation (SNP) | VAF 96/788 reads (12%) | catalogued as rs1555603114, COSV101438649; called by muse, mutect2, varscan2
- SCN5A | c.3688G>T p.E1230* (on ENST00000333535 / NM_198056.3; = p.E1229* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 72/366 reads (20%) | catalogued as rs779669888; called by muse, varscan2
- SCNN1G | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 521/758 reads (69%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.834); catalogued as COSV55602218; called by muse, mutect2, varscan2
- SCO1 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 370/388 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV104370749; called by muse, mutect2, varscan2
- SCUBE1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 214/914 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs372229798; called by muse, varscan2
- SEC31B | c.2738C>T p.S913F | Missense Mutation (SNP) | VAF 169/666 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV64845724; called by muse, varscan2
- SEPTIN3 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 457/876 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.514); catalogued as rs773006308; called by muse, mutect2, varscan2
- SERPINA7 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 350/728 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs778707647, COSV59665835; called by muse, varscan2
- SERPINB2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 244/690 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55091593; called by muse, mutect2, varscan2
- SERPINI1 | c.1071G>A p.M357I | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.399); catalogued as rs1168773849; called by muse, mutect2
- SGCG | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 38/162 reads (23%) | catalogued as COSV54557672, COSV54562563; called by muse, mutect2, varscan2
- SGTB | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 156/261 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188020758; called by muse, mutect2, varscan2
- SH3TC2 | c.2384C>T p.S795F | Missense Mutation (SNP) | VAF 307/489 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV60463516; called by muse, mutect2, varscan2
- SH3TC2 | c.947G>C p.G316A | Missense Mutation (SNP) | VAF 235/399 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1251082752; called by muse, mutect2, varscan2
- SHANK1 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 130/573 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs368633151; called by muse, mutect2, varscan2
- SHISA3 | c.278-1G>A p.X93_splice | Splice Site (SNP) | VAF 211/229 reads (92%) | catalogued as COSV100069777; called by muse, mutect2, varscan2
- SHISA9 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 523/764 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV101376164, COSV69642083; called by muse, varscan2
- SHOC1 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 183/194 reads (94%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs755547424; called by muse, mutect2, varscan2
- SHOC1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 159/174 reads (91%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59503954; called by muse, mutect2, varscan2
- SI | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs764555878, COSV52297210; called by muse, mutect2, varscan2
- SIGLEC1 | c.2651C>T p.S884L | Missense Mutation (SNP) | VAF 111/475 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750926735; called by muse, mutect2, varscan2
- SIRPG | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 123/597 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53806943; called by muse, varscan2
- SKIV2L | c.1927C>T p.L643F | Missense Mutation (SNP) | VAF 354/1117 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs761742617, COSV64812591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC12A3 | c.2561G>A p.R854K (on ENST00000563236 / NM_001126108.2; = p.R863K on NM_000339.3) | Missense Mutation (SNP) | VAF 86/422 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs8060046; called by muse, mutect2, varscan2
- SLC14A2 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 357/668 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54912966; called by muse, varscan2
- SLC16A12 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 104/519 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1287452968, COSV57950501; called by muse, mutect2, varscan2
- SLC17A8 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 99/421 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV60126629; called by muse, mutect2, varscan2
- SLC1A5 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 377/526 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV69467160, COSV69467166; called by muse, varscan2
- SLC22A5 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 157/514 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM104592; called by muse, varscan2
- SLC24A3 | c.714-1G>A p.X238_splice | Splice Site (SNP) | VAF 60/336 reads (18%) | catalogued as COSV60110494; called by muse, mutect2, varscan2
- SLC26A7 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 370/584 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV52590518; called by muse, varscan2
- SLC2A7 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 126/1002 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV68901924; called by muse, mutect2, varscan2
- SLC36A2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 254/411 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100079457; called by muse, mutect2, varscan2
- SLC45A1 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 182/1258 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs200084739, COSV57092959; called by muse, varscan2
- SLC4A5 | c.2311C>T p.P771S | Missense Mutation (SNP) | VAF 172/473 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs866262420, COSV61025711; called by muse, mutect2, varscan2
- SLC4A9 | c.2467G>A p.G823R (on ENST00000507527 / NM_001258428.2; = p.G799R on NM_031467.3) | Missense Mutation (SNP) | VAF 204/359 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50184430; called by muse, varscan2
- SLC7A2 | c.637G>A p.G213R (on ENST00000494857 / NM_001370338.1; = p.G253R on NM_003046.6) | Missense Mutation (SNP) | VAF 356/497 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99135939; called by muse, mutect2, varscan2
- SLC8A3 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 297/823 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV63524809; called by muse, varscan2
- SLC8A3 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 278/814 reads (34%) | catalogued as rs889723304, COSV100775813, COSV63520541; called by muse, varscan2
- SLC9C2 | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 129/271 reads (48%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.911); catalogued as rs1456305392; called by muse, mutect2, varscan2
- SLIT1 | c.2498C>T p.S833F | Missense Mutation (SNP) | VAF 282/420 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868277232, COSV104382514; called by muse, varscan2
- SMC1B | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 270/577 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs748923396, COSV62529887; called by muse, varscan2
- SMCHD1 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1178345431; called by muse, varscan2
- SMO | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 116/956 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs774627960, COSV104374869; called by muse, mutect2, varscan2
- SORCS3 | c.2153G>A p.R718K | Missense Mutation (SNP) | VAF 226/337 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs776440027, COSV63799455; called by muse, mutect2, varscan2
- SORCS3 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 282/401 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV63794510; called by muse, varscan2
- SORD | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 182/340 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867888668; called by muse, mutect2, varscan2
- SP140 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 172/316 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.272); catalogued as rs201257053; called by muse, varscan2
- SPANXN3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 326/747 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.991); catalogued as COSV65140742; called by muse, varscan2
- SPARCL1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 278/295 reads (94%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs140130359; called by muse, mutect2, varscan2
- SPAST | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 136/399 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV59512593; called by muse, mutect2, varscan2
- SPATA13 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754626684; called by muse, mutect2, varscan2
- SPATA16 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 252/369 reads (68%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV63528247; called by muse, varscan2
- SPATA16 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 91/481 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs144595913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA5L1 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 176/289 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs776098345, COSV99972808; called by muse, mutect2, varscan2
- SPEG | c.8156C>T p.S2719F | Missense Mutation (SNP) | VAF 112/362 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV56674777; called by muse, varscan2
- SPHKAP | c.4625G>A p.R1542Q | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs368367152, COSV60881066; called by muse, varscan2
- SPPL2A | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as COSV55941481, COSV55943050; called by muse, mutect2, varscan2
- SPSB4 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 351/811 reads (43%) | catalogued as COSV60150125; called by muse, varscan2
- SPTB | c.4783G>A p.E1595K | Missense Mutation (SNP) | VAF 370/952 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs756327499, COSV67631249; called by muse, mutect2, varscan2
- SPTLC3 | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 338/463 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100982956; called by muse, mutect2, varscan2
- SRL | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 98/516 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as rs1295137726, COSV68423078; called by muse, mutect2
- ST6GALNAC5 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 145/766 reads (19%) | PolyPhen possibly damaging (0.67); catalogued as rs746598078, COSV59562032, COSV59564346; called by muse, varscan2
- ST6GALNAC5 | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 435/1103 reads (39%) | PolyPhen possibly damaging (0.783); catalogued as COSV100602811; called by muse, mutect2, varscan2
- ST8SIA4 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 151/262 reads (58%) | PolyPhen probably damaging (0.988); catalogued as rs868733908, COSV51509166; called by muse, mutect2, varscan2
- STARD9 | c.10643C>T p.A3548V | Missense Mutation (SNP) | VAF 126/447 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as rs1427752586; called by muse, mutect2, varscan2
- STC2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.456); catalogued as rs143646937; called by muse, varscan2
- STXBP4 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 117/308 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV100894674; called by muse, varscan2
- SVIL | c.4039G>A p.E1347K (on ENST00000355867 / NM_021738.3; = p.E921K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 203/565 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV63442036; called by muse, varscan2
- SYCP1 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 280/358 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65698859; called by muse, mutect2, varscan2
- SYNE1 | c.21950C>T p.S7317F (on ENST00000367255 / NM_182961.4; = p.S7246F on NM_033071.3) | Missense Mutation (SNP) | VAF 223/501 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs981484025; called by muse, mutect2, varscan2
- SYNE1 | c.1468C>T p.H490Y (on ENST00000367255 / NM_182961.4; = p.H497Y on NM_033071.3) | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV54897967; called by muse, mutect2, varscan2
- SYNE3 | c.2701C>T p.P901S | Missense Mutation (SNP) | VAF 228/674 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs1354196722; called by muse, varscan2
- SYT1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs138582600, COSV54034805; called by muse, mutect2, varscan2
- SYT10 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 250/382 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs767119363, COSV57338723; called by muse, varscan2
- SYT3 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 220/874 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs771552981; called by muse, mutect2, varscan2
- SYT4 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 392/708 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV54903170; called by muse, varscan2
- TACC2 | c.8554-1G>A p.X2852_splice (on ENST00000334433; = p.X930_splice on NM_006997.4) | Splice Site (SNP) | VAF 207/317 reads (65%) | catalogued as COSV53278827, COSV99586836; called by muse, mutect2, varscan2
- TAOK2 | c.2830C>T p.P944S | Missense Mutation (SNP) | VAF 610/898 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV54238089; called by muse, varscan2
- TAS1R2 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 312/861 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV104428081; called by muse, mutect2, varscan2
- TBC1D25 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 308/638 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV100952102; called by muse, varscan2
- TEF | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 528/1034 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764930328; called by muse, varscan2
- TENM1 | c.6616G>A p.G2206R | Missense Mutation (SNP) | VAF 232/569 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64431633; called by muse, mutect2, varscan2
- TEP1 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 459/815 reads (56%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs939722304; called by muse, mutect2, varscan2
- TEPP | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 394/597 reads (66%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.548); catalogued as rs539938986; called by muse, varscan2
- TESK1 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 506/554 reads (91%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs756272696; called by muse, varscan2
- TET2 | c.4555G>A p.G1519R | Missense Mutation (SNP) | VAF 121/404 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs753711986; called by muse, varscan2
- TEX15 | c.4729A>C p.I1577L (on ENST00000256246; = p.I1960L on NM_001350162.2) | Missense Mutation (SNP) | VAF 96/406 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56341802; called by muse, varscan2
- TFAP2D | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 369/612 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); catalogued as rs778560524, COSV50407961; called by muse, mutect2, varscan2
- TGM2 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 89/483 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs776355908, COSV63932431; called by muse, varscan2
- TLE2 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 164/262 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs1290850468, COSV99504510; called by muse, mutect2, varscan2
- TLNRD1 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 205/639 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs769785232; called by muse, varscan2
- TMCC3 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 94/344 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs144548464; called by muse, mutect2, varscan2
- TMCO2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); catalogued as rs750978469, COSV65646643; called by muse, varscan2
- TMEM131L | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs1419635686; called by muse, varscan2
- TMEM132C | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 139/491 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1362798425; called by muse, mutect2, varscan2
- TMEM132C | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 174/662 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as rs867717839, COSV59433766; called by muse, varscan2
- TMEM132D | c.2550G>A p.M850I | Missense Mutation (SNP) | VAF 154/515 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs377746256; called by muse, mutect2, varscan2
- TMEM211 | c.302G>A p.R101K (on ENST00000423535; = p.R30K on NM_001001663.3) | Missense Mutation (SNP) | VAF 439/1101 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV66954153; called by muse, mutect2, varscan2
- TMEM225 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 217/227 reads (96%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1310598409, COSV66692956; called by muse, mutect2, varscan2
- TMEM225 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 180/214 reads (84%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV66693518; called by muse, mutect2, varscan2
- TMIGD2 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 145/580 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1288484768, COSV56667322; called by muse, mutect2, varscan2
- TNC | c.5699C>T p.S1900L | Missense Mutation (SNP) | VAF 303/325 reads (93%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs775636762, COSV60782271; called by muse, mutect2, varscan2
- TNIK | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 455/638 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs767165156; called by muse, mutect2, varscan2
- TNK2 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 567/790 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs143850445, COSV100360813; called by muse, mutect2, varscan2
- TNR | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 311/331 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54887612; called by muse, mutect2, varscan2
- TNRC18 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 255/565 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1006455062; called by muse, mutect2, varscan2
- TOX2 | c.1070G>A p.R357Q (on ENST00000358131 / NM_001098798.2; = p.R333Q on NM_032883.3) | Missense Mutation (SNP) | VAF 726/985 reads (74%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.978); catalogued as rs773686339, COSV57882392; called by muse, mutect2, varscan2
- TPP1 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 133/435 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as rs748686068, COSV100197018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPRX1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 224/1118 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.127); catalogued as rs201315320; called by muse, varscan2
- TRANK1 | c.2248G>A p.G750S | Missense Mutation (SNP) | VAF 617/907 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs758736732; called by muse, varscan2
- TREM1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 311/1043 reads (30%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.802); catalogued as COSV55149310; called by muse, mutect2, varscan2
- TREML2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 298/1276 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs762890750, COSV72438998; called by muse, varscan2
- TRIM55 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 154/982 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as CM146844; called by muse, mutect2, varscan2
- TRIM67 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 190/568 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs891200251; called by muse, mutect2, varscan2
- TRIM77 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 174/195 reads (89%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV68067283; called by muse, mutect2, varscan2
- TRMT10C | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 315/465 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185897256; called by muse, mutect2, varscan2
- TRPC4 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 78/319 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV59020701; called by muse, varscan2
- TRPC6 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 50/56 reads (89%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV60252193; called by muse, mutect2, varscan2
- TRPC7 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 311/480 reads (65%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as rs1211795803; called by muse, mutect2, varscan2
- TRPC7 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs773517278; called by muse, mutect2, varscan2
- TSHZ2 | c.2924C>T p.S975L | Missense Mutation (SNP) | VAF 268/705 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.14); catalogued as rs267606003, COSV61586685; called by muse, mutect2, varscan2
- TSSK1B | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 149/585 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761618235; called by muse, mutect2, varscan2
- TTLL2 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 173/393 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs748651103, COSV53445233; called by muse, mutect2, varscan2
- TTN | c.94933G>A p.E31645K (on ENST00000591111; = p.E24221K on NM_003319.4) | Missense Mutation (SNP) | VAF 103/184 reads (56%) | PolyPhen probably damaging (0.99); catalogued as rs780655169; called by muse, mutect2, varscan2
- TTN | c.75781C>T p.P25261S (on ENST00000591111; = p.P17837S on NM_003319.4) | Missense Mutation (SNP) | VAF 147/255 reads (58%) | PolyPhen possibly damaging (0.772); catalogued as rs1024262797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.69268G>A p.E23090K (on ENST00000591111; = p.E15666K on NM_003319.4) | Missense Mutation (SNP) | VAF 114/394 reads (29%) | PolyPhen benign (0.298); catalogued as rs186780326, COSV59902383; called by muse, mutect2, varscan2
- TTN | c.56570C>T p.A18857V (on ENST00000591111; = p.A11433V on NM_003319.4) | Missense Mutation (SNP) | VAF 236/422 reads (56%) | PolyPhen possibly damaging (0.674); catalogued as rs145131899; called by muse, varscan2
- TTN | c.54610C>T p.R18204C (on ENST00000591111; = p.R10780C on NM_003319.4) | Missense Mutation (SNP) | VAF 126/414 reads (30%) | PolyPhen benign (0.017); catalogued as rs1232069163, COSV60071060, COSV60191978; called by muse, mutect2, varscan2
- TTN | c.47836G>A p.E15946K (on ENST00000591111; = p.E8522K on NM_003319.4) | Missense Mutation (SNP) | VAF 119/408 reads (29%) | PolyPhen benign (0.098); catalogued as rs1271096467, COSV60231715; called by muse, mutect2, varscan2
- TTN | c.36412C>T p.P12138S (on ENST00000591111; = p.P4714S on NM_003319.4) | Missense Mutation (SNP) | VAF 172/274 reads (63%) | PolyPhen probably damaging (0.998); catalogued as COSV60379178; called by muse, varscan2
- TTN | c.33914C>T p.P11305L (on ENST00000591111; = p.P10378L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/271 reads (25%) | PolyPhen benign (0); catalogued as rs574102745, COSV60164844; called by muse, mutect2, varscan2
- TTN | c.14396G>A p.R4799Q (on ENST00000591111; = p.R3872Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 202/338 reads (60%) | PolyPhen possibly damaging (0.594); catalogued as rs769626460, COSV100629560; called by muse, mutect2, varscan2
- TTN | c.11059G>A p.E3687K (on ENST00000591111; = p.E3641K on NM_003319.4) | Missense Mutation (SNP) | VAF 139/422 reads (33%) | catalogued as rs755242569, COSV59954793; called by muse, mutect2, varscan2
- TTN | c.6322G>A p.E2108K (on ENST00000591111; = p.E2062K on NM_003319.4) | Missense Mutation (SNP) | VAF 167/493 reads (34%) | PolyPhen probably damaging (0.994); catalogued as rs762999586, COSV60013101; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TUBA3C | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 148/525 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as rs868127144, COSV68029500; called by muse, varscan2
- TUBA3C | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 179/697 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); catalogued as rs373201894, COSV67139696, COSV67139935; called by muse, varscan2
- UGT3A1 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 683/1232 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as COSV57096535; called by muse, varscan2
- UNC13C | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 171/296 reads (58%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs565877113, COSV52873149, COSV99509498; called by muse, mutect2, varscan2
- UNC79 | c.3562C>T p.P1188S (on ENST00000393151 / NM_001346218.2; = p.P1011S on NM_020818.5) | Missense Mutation (SNP) | VAF 231/421 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.334); catalogued as COSV56379087; called by muse, mutect2, varscan2
- UNC93A | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 360/387 reads (93%) | catalogued as rs895339426; called by muse, varscan2
- USH2A | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 304/337 reads (90%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs369806765, CM135886, COSV100240811; called by muse, mutect2, varscan2
- USP29 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 131/318 reads (41%) | catalogued as COSV54237626; called by muse, varscan2
- USP29 | c.2572G>A p.D858N | Missense Mutation (SNP) | VAF 404/591 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756825168, COSV54140150, COSV54144117; called by muse, mutect2, varscan2
- VCX3A | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 204/1328 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs781337353, COSV101129906; called by muse, varscan2
- VEGFD | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 105/528 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770666075; called by muse, mutect2, varscan2
- VN1R4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV60805055; called by muse, mutect2, varscan2
- VPREB1 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 386/795 reads (49%) | catalogued as COSV100164837; called by muse, mutect2, varscan2
- VPS13A | c.5506C>T p.H1836Y | Missense Mutation (SNP) | VAF 86/180 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770055324; called by muse, mutect2, varscan2
- VSTM2B | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 294/419 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.563); catalogued as rs909870985; called by muse, mutect2, varscan2
- VSTM4 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 462/677 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV53678593; called by muse, mutect2
1,764 further variants in this file (857 protein-altering or splice-affecting, 809 silent, 98 other) are not listed here.
